Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5893, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5893-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Large left renal mass please correlate with FNA of cervical lymph node.

Specimens Submitted:

- 1: SP: Left kidney, radical nephrectomy
- 2: SP: Hilar lymph nodes, excision
- 3: SP: Inferior mesentery artery lymph nodes, excision
- 4: SP: Para aortic lymph nodes #1, excision
- 5: SP: Para aortic lymph nodes #2, excision
- 6: SP: Left hilar lymph nodes, excision
- 7: SP: Left adrenal gland, adrenalectomy
- 8: SP: Mesentary lymph nodes, excision

DIAGNOSIS:

1. SP: Left kidney, radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Unclassified type
favor collecting duct type (see note)

Tumor Size:

Two masses identified (15 and 3 cm, respectively)

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Extends into renal pelvis
Involves renal sinus fat
Involves renal hilar fat

Renal Vein Invasion:

Not identified
Extensive small vessel and lymphatic invasion identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

see parts 6 and 7

Lymph Nodes:

Number of metastatic nodes:1
Number of nodes examined:1

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

NOTE: IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED BUT ARE NON-CONTRIBUTORY. BASED ON THE MORPHOLOGIC FEATURES, WE FAVOR THIS TUMOR TO BE OF COLLECTING DUCT ORIGIN (COLLECTING DUCT CARCINOMA). CASE REVIEWED AT THE GENITOURINARY CONSENSUS CONFERENCE

2. SP: Hilar lymph nodes, excision:

Lymph Nodes:

Metastatic carcinoma involving adipose tissue, measuring 5.8 cm. No lymphoid tissue identified

3. SP: Inferior mesentery artery lymph nodes, excision:

Lymph Nodes:

Number of nodes examined:2

Number of metastatic nodes:2

The largest metastatic node is 1.5cm

Perinodal (extracapsular) extension not identified

4. SP: Para aortic lymph nodes #1, excision:

Lymph Nodes:

Number of nodes examined:1

Number of metastatic nodes:1

The largest metastatic node is 4.5cm

Perinodal (extracapsular) extension not identified

5. SP: Para aortic lymph nodes #2, excision:

Lymph Nodes:

Number of nodes examined:11

Number of metastatic nodes:11

The largest metastatic node is 6.0cm

Perinodal (extracapsular) extension not identified

6. SP: Left hilar lymph nodes, excision:

Lymph Nodes:

Number of nodes examined:14

Number of metastatic nodes:14

The largest metastatic node is 6.2cm

Perinodal (extracapsular) extension not identified

Portion of adrenal gland involved by metastatic carcinoma.

7. Left adrenal gland, adrenalectomy:

-Metastatic carcinoma involving adrenal gland.

8. SP: Mesentery lymph nodes, excision:

Lymph Nodes:

Number of nodes examined:2

Number of metastatic nodes:2

The largest metastatic node is 2.0cm

Perinodal (extracapsular) extension not identified

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

NOTE: THIS TUMOR IS COMPATIBLE AS THE PRIMARY SITE OF ORIGIN FOR MATERIAL RECEIVED FROM THE PRIOR CYTOLOGY SPECIMEN FROM THE LEFT NECK LYMPH NODE [REDACTED]

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CK7	
	CK20	
	34BE12	
	CD10	
	CA-1X	
	TTF-1	
	CD117	
	MUCIN	
	IMM RECUT	
	NEG CONT	
	RACEMASE	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1) The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1478 g in total. The kidney measures 19.5 x 14.0 x 9.0 cm. The attached ureter measures 12cm in length and 0.5 cm in diameter. The attached renal vein measures 2 cm in length and 1.2 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal 2 tumors. The first measures 15 x 13 x 12 cm. The second measures 3.0 x 2.2 x 1.9 cm and is located in the opposite pole. Both have yellow-white cystic and focally hemorrhagic cut surfaces. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. A 0.5 cm polyp is noted in the renal pelvis. One possible lymph node is identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections (including polyp)
T2--smaller tumor
K -- representative sections kidney
LN- possible lymph nodes

2). The specimen is received fresh, labeled "Hilar lymph node" and consists of an enlarged firm lymph node with scant attached adipose tissue measuring 5.8 x 3.5 x 3.2 cm. on cut section the specimen, it shows soft, necrotic, white-tan tumor. Representatives sections are submitted.

Summary of sections:

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

LN- lymph node

3). The specimen is received fresh labeled "Inferior mesenteric artery lymph node." It consists of two firm brown-tan lymph nodes measuring 1.0 x 0.8 x 0.4 cm and 1.5 x 1.2 x 0.8 cm. Larger lymph node is inked black and bisected. Lymph nodes are entirely submitted.

Summary of sections:
LN-lymph nodes

4). The specimen is received fresh, labeled "Para-aortic lymph node number one" and consists of a single firm brown-tan lymph node measuring 4.0 x 2.7 x 1.7 cm. Representative sections are submitted..

Summary of sections:
LN- lymph node

5). The specimen is received in formalin labeled "Paraaortic lymph nodes #2" and consists of multiple pink tan firm lymph nodes with attached fatty fibrous tissue ranging from 0.4 cm up to 6.0 cm in greatest dimension. Lymph node have a white firm papillary cut surface, the remaining lymph nodes are entirely submitted. TPS of the largest positive lymph node is submitted. All identified lymph nodes are submitted.

Summary of sections:
LN1 - grossly positive lymph node
LN2 - grossly positive lymph node
LN3 - grossly positive lymph node
LN4 - grossly positive lymph node
LN5 - grossly positive lymph node
LN6 - grossly positive lymph node
LN7 - grossly positive lymph node
LN8 - grossly positive lymph node
BLN-bisected lymph nodes
LN-- lymph nodes

6). The specimen is received in formalin labeled "Left hilar lymph nodes" and consists of multiple pink tan firm lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 6.2 cm in greatest dimension. Lymph node have a white firm papillary cut surface, the remaining lymph nodes are entirely submitted. TPS of the largest positive lymph node is submitted. All identified lymph nodes are submitted.

Summary of sections:
LN1 - grossly positive lymph node
LN2 - grossly positive lymph node
LN3 - grossly positive lymph node
LN4 - grossly positive lymph node
LN5 - grossly positive lymph node
LN6 - grossly positive lymph node
LN7 - grossly positive lymph node
LN8 - grossly positive lymph node
LN9 - grossly positive lymph node
LN10 - grossly positive lymph node
LN11 - grossly positive lymph node

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

BLN-bisected lymph nodes
LN--lymph nodes

7). The specimen is received in formalin, labeled "Left adrenal gland" and consists of a 8 x 5x 3 cm portion of tan fibrofatty tissue, which weighs 47grams. The specimen is inked black. On cut section a 3.7 x 3 x 2.5cm orange adrenal gland is identified. There is a markedly, indurated, fleshy, hemorrhagic area, measuring 1.4 x 0.6 x 1cm located on the peripheral of the gland. The remaining parenchyma reveal firm, orange glandular cut surface. No lymph nodes are identified on the peri-adrenal fat. Representatively submitted.

Summary of sections:
RS - representative sections

8). The specimen is received in formalin, labeled "Mesenteric lymph node" and consists of a single white tan firm positive lymph node measuring 2 x 1.2 x 0.8 cm. The lymph node is bisected and entirely submitted.

Summary of sections:
BLN- bisected a lymph node

Summary of Sections:

Part 1: SP: Left kidney, radical nephrectomy

Block	Sect. Site	PCs
1	k	1
1	ln	1
1	rp	1
10	t	10
3	t2	3
1	thf	1
1	tk	1
1	tsf	1
1	um	1
1	vm	1

Part 2: SP: Hilar lymph nodes, excision

Block	Sect. Site	PCs
1	LN	1

Part 3: SP: Inferior mesentery artery lymph nodes, excision

Block	Sect. Site	PCs
1	LN	1

Part 4: SP: Para aortic lymph nodes #1, excision

Block	Sect. Site	PCs
1	ln	1

Part 5: SP: Para aortic lymph nodes #2, excision

Block	Sect. Site	PCs
3	bln	3
1	ln	1
1	ln1	1
1	ln2	1
1	ln3	1

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1	In4	1
1	In5	1
1	In6	1
1	In7	1
1	In8	1

Part 6: SP: Left hilar lymph nodes, excision

Block	Sect. Site	PCs
3	bln	3
2	In	2
1	In1	1
1	In10	1
1	In11	1
1	In2	1
1	In3	1
1	In4	1
1	In5	1
1	In6	1
1	In7	1
1	In8	1
1	In9	1

Part 7: SP: Left adrenal gland, adrenalectomy

Block	Sect. Site	PCs
5	RS	5

Part 8: SP: Mesentary lymph nodes, excision

Block	Sect. Site	PCs
2	BLN	3

Source: NCI Genomic Data Commons file 04df74c0-d2d8-4fcb-9d2f-c4f43be02218 (TCGA-BQ-5893.9714096E-F30D-4467-BC8E-D5B7AA6A72BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).